Gene-level copy-number profile of tumor specimen ALCH-B1OR-TTP1-A from ALCHEMIST case ALCH-B1OR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.6 years (29,803 days).
Specimen ALCH-B1OR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 169be6bb-b572-4969-a283-b75bab15dc81.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/34eb3461-ea7d-45ce-9adc-3396a16ed500

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,189; copy number 2: 51,537; copy number 3: 5,640; copy number 4: 15; copy number 5: 5; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:231,706,895–231,713,551, 3 genes (within-gene range 0–1): PTMA, U4, MIR1244-1.
- chr15:90,883,695–90,922,584, 3 genes (within-gene range 0–1): FES, MAN2A2, AC068831.3.
- chr16:33,802,764–33,810,767, 2 genes: IGHV3OR16-12, AC136428.3.
- chr16:89,818,179–89,871,319, 1 gene: SPIRE2.
- chr22:38,426,327–38,483,447, 3 genes (within-gene range 0–2): KCNJ4, Z97056.3, KDELR3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:131,125,586–131,234,663, 1 gene, copy number 5 (within-gene range 2–5): NUP214.
- chr9:131,132,852–131,194,205, 2 genes, copy number 5: AL157938.2, AL157938.3.
- chr19:1,228,287–1,239,522, 2 genes, copy number 5–6 (within-gene range 3–6): CBARP, AC004221.1.
- chr20:63,502,287–63,505,111, 1 gene, copy number 5: AL121829.1.

Autosomal genes at a single copy (total copy number 1): 1,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
